Somatic mutation profile of tumor specimen MMRF_1889_3_BM_CD138pos (aliquot MMRF_1889_3_BM_CD138pos_T1_KHS5U_K15220) from MMRF case MMRF_1889, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.3 years (22,773 days).
Specimen MMRF_1889_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1688197c-7a2a-404e-8632-4268adb2eaf8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1889_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1889_2_PB_Whole_C3_KBS5U_L07242; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c5a8c81-4d53-49c6-bed3-ade3271a6b66

The open-access MAF lists 141 somatic variants for this specimen: 58 protein-altering or splice-affecting, 13 silent, 70 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, 3'UTR 38, Intron 16, Silent 13, 5'UTR 5, 3'Flank 5, RNA 3, 5'Flank 3, Frame Shift Del 2, Frame Shift Ins 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 59/126 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BCO1 | c.1493C>T p.T498M | Missense Mutation (SNP) | VAF 78/80 reads (98%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs375017107; called by muse, mutect2, varscan2
- CDKN1B | c.410del p.P137Rfs*8 | Frame Shift Del (DEL) | VAF 52/74 reads (70%) | catalogued as rs1328655695, COSV99964122; called by mutect2, pindel, varscan2
- CHRM1 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs1007009594, COSV61006154; called by muse, mutect2, varscan2
- CTC1 | c.2146C>T p.Q716* | Nonsense Mutation (SNP) | VAF 49/104 reads (47%) | catalogued as COSV59853547; called by muse, mutect2, varscan2
- IGLL5 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV101597175; called by muse, mutect2
- IGLV3-1 | c.135A>T p.K45N | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs183724895; called by muse, mutect2, varscan2
- INTS13 | c.2071G>C p.E691Q | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.419); catalogued as rs1431375236, COSV53904462; called by muse, mutect2, varscan2
- KLK15 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 80/154 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56828361; called by muse, mutect2, varscan2
- MAP3K15 | c.2881G>A p.A961T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs765404542, COSV58829723; called by muse, mutect2, varscan2
- MYADM | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 103/229 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs889083260; called by muse, mutect2, varscan2
- OCA2 | c.1657G>A p.V553I | Missense Mutation (SNP) | VAF 157/224 reads (70%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.572); catalogued as rs552418165, COSV62339253, COSV62347333; called by muse, mutect2, varscan2
- PIK3R5 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777086538, COSV52655561; called by muse, mutect2, varscan2
- RBM3 | c.42C>A p.N14K | Missense Mutation (SNP) | VAF 115/399 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100618781; called by muse, mutect2, varscan2
- RNF17 | c.3973A>G p.M1325V | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT tolerated (0.22); PolyPhen benign (0.166); catalogued as rs868562390; called by muse, mutect2, varscan2
- SLC26A7 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV104372275; called by muse, mutect2, varscan2
- SYBU | c.1852G>A p.V618M (on ENST00000276646 / NM_001099754.2; = p.V617M on NM_017786.6) | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as rs762659962; called by muse, mutect2, varscan2
- TAS1R1 | c.1486G>T p.V496L | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.196); catalogued as rs1229246165, COSV59839849; called by muse, mutect2, varscan2
- ABCA13 | c.8821C>A p.L2941I | Missense Mutation (SNP) | VAF 66/211 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- ABCC12 | c.3559A>T p.I1187F | Missense Mutation (SNP) | VAF 41/44 reads (93%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ACTL6B | c.1054A>G p.T352A | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- ADAMTS16 | c.3244T>G p.Y1082D | Missense Mutation (SNP) | VAF 84/130 reads (65%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AGRN | c.2072G>T p.G691V | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CACNA1B | c.3259C>T p.P1087S | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- CDH18 | c.1072T>C p.F358L | Missense Mutation (SNP) | VAF 143/204 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CDH7 | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- CGN | c.815G>T p.W272L | Missense Mutation (SNP) | VAF 83/112 reads (74%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CILP2 | c.1670A>C p.K557T | Missense Mutation (SNP) | VAF 247/386 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- COL20A1 | c.79C>G p.Q27E | Missense Mutation (SNP) | VAF 103/242 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CYFIP2 | c.2293C>A p.P765T (on ENST00000616178 / NM_001291722.2; = p.P740T on NM_014376.4) | Missense Mutation (SNP) | VAF 70/256 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DNAH9 | c.6251C>T p.T2084I | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- EBF2 | c.1051C>A p.Q351K | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- EVC2 | c.1914G>T p.M638I | Missense Mutation (SNP) | VAF 88/174 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- IGHV1-69D | c.89T>C p.V30A | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.308); called by muse, varscan2
- INTS9 | c.1046dup p.H349Qfs*6 | Frame Shift Ins (INS) | VAF 47/139 reads (34%) | called by mutect2, pindel, varscan2
- ITGA4 | c.1770A>C p.K590N | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- KMT2B | c.5730dup p.R1911Qfs*61 | Frame Shift Ins (INS) | VAF 54/135 reads (40%) | called by mutect2, pindel, varscan2
- LAMA1 | c.7956C>A p.F2652L | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LLGL1 | c.3089C>T p.T1030I | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- MAEL | c.1279T>C p.Y427H | Missense Mutation (SNP) | VAF 113/162 reads (70%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- MON1A | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MPP5 | c.1886G>C p.R629T | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MTMR8 | c.325C>A p.L109I | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- MUC16 | c.11534C>A p.T3845N | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- OIT3 | c.950A>T p.D317V | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- PLEKHM1 | c.638A>G p.E213G | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PTPRO | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- RPL23A | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- SHISA6 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SLC16A3 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 67/99 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- STEAP4 | c.20A>T p.D7V | Missense Mutation (SNP) | VAF 83/273 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TBX5 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- TENT5C | c.888del p.F296Lfs*13 | Frame Shift Del (DEL) | VAF 57/150 reads (38%) | called by mutect2, pindel, varscan2
- TRPM4 | c.224A>T p.Y75F | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.92); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- VIRMA | c.188C>G p.S63C | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- WDFY4 | c.2699C>A p.P900H | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ZNF169 | c.1804G>C p.V602L | Missense Mutation (SNP) | VAF 127/394 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF302 | c.1181G>A p.C394Y (on ENST00000627982; = p.C315Y on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 91/306 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARSF | c.174C>A p.I58= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as rs758361610; called by mutect2, varscan2
- CDKL5 | c.2673G>A p.Q891= | Silent (SNP) | VAF 57/131 reads (44%) | catalogued as rs373448935; ClinVar: likely benign; called by muse, mutect2, varscan2
- GLDC | c.564C>G p.G188= | Silent (SNP) | VAF 33/82 reads (40%) | called by muse, mutect2, varscan2
- GRIN3A | c.636C>T p.V212= | Silent (SNP) | VAF 97/309 reads (31%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.225T>C p.D75= | Silent (SNP) | VAF 48/97 reads (49%) | catalogued as rs373801344; called by muse, varscan2
- INAVA | c.1590G>T p.L530= | Silent (SNP) | VAF 18/20 reads (90%) | called by muse, mutect2
- MCM10 | c.117C>T p.P39= | Silent (SNP) | VAF 130/304 reads (43%) | called by muse, mutect2, varscan2
- PLXNB1 | c.4920G>T p.L1640= | Silent (SNP) | VAF 128/236 reads (54%) | called by muse, mutect2, varscan2
- RASL11B | c.396C>T p.L132= | Silent (SNP) | VAF 86/156 reads (55%) | called by muse, mutect2, varscan2
- SOX3 | c.198G>A p.T66= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as rs1038380785; called by muse, mutect2, varscan2
- TNPO3 | c.2454G>C p.R818= | Silent (SNP) | VAF 39/140 reads (28%) | called by muse, mutect2, varscan2
- TTN | c.57688C>T p.L19230= (on ENST00000591111; = p.L11806= on NM_003319.4) | Silent (SNP) | VAF 101/232 reads (44%) | called by muse, mutect2, varscan2
- TYR | c.618T>A p.A206= | Silent (SNP) | VAF 18/272 reads (7%) | called by muse, mutect2
- ABCB9 | c.1743+100T>A | Intron (SNP) | VAF 21/36 reads (58%) | called by muse, mutect2, varscan2
- AC020907.6 | c.-501C>G | 5'UTR (SNP) | VAF 113/413 reads (27%) | called by muse, mutect2, varscan2
- ADARB1 | c.*4286C>T | 3'UTR (SNP) | VAF 33/108 reads (31%) | called by muse, mutect2, varscan2
- AFAP1 | chr4:7940118 C>A | 5'Flank (SNP) | VAF 6/147 reads (4%) | called by muse, mutect2
- AR | c.*6540G>T | 3'UTR (SNP) | VAF 14/46 reads (30%) | catalogued as rs1449903184; called by muse, mutect2, varscan2
- ARNTL2 | chr12:27421413 C>T | 3'Flank (SNP) | VAF 150/294 reads (51%) | called by muse, varscan2
- ARNTL2 | chr12:27421867 C>T | 3'Flank (SNP) | VAF 23/58 reads (40%) | called by muse, varscan2
- ARNTL2 | chr12:27422085 C>T | 3'Flank (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- ARPC4 | c.*916G>A | 3'UTR (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- ASF1B | c.*290_*292dup | 3'UTR (INS) | VAF 29/128 reads (23%) | called by mutect2, pindel, varscan2
- B4GALT6 | chr18:31622758 A>T | 3'Flank (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- BNIP3L | c.*986G>A | 3'UTR (SNP) | VAF 11/29 reads (38%) | catalogued as rs1168330674; called by muse, mutect2, varscan2
- C15orf54 | n.427C>T | RNA (SNP) | VAF 24/76 reads (32%) | catalogued as rs770581044; called by muse, mutect2, varscan2
- CCNYL2 | n.624-2485C>A | Intron (SNP) | VAF 51/110 reads (46%) | called by muse, mutect2, varscan2
- CERS6 | c.*3056C>G | 3'UTR (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- CNGA3 | c.*781A>G | 3'UTR (SNP) | VAF 30/54 reads (56%) | called by muse, mutect2, varscan2
- CRYBG1 | c.*874C>A | 3'UTR (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- CTNND2 | c.*647C>T | 3'UTR (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- DAZL | c.-208C>G | 5'UTR (SNP) | VAF 4/9 reads (44%) | called by mutect2, varscan2
- DGKB | c.1287+25T>C | Intron (SNP) | VAF 83/127 reads (65%) | called by muse, mutect2, varscan2
- EOMES | c.*600T>G | 3'UTR (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- EPHA5 | c.*222A>G | 3'UTR (SNP) | VAF 33/48 reads (69%) | called by muse, mutect2, varscan2
- FAM9B | c.-50C>T | 5'UTR (SNP) | VAF 172/333 reads (52%) | catalogued as COSV59118936; called by muse, mutect2, varscan2
- FBXL21P | n.1540T>C | RNA (SNP) | VAF 33/83 reads (40%) | called by muse, mutect2, varscan2
- FLT4 | c.2647+32A>T | Intron (SNP) | VAF 41/123 reads (33%) | called by muse, mutect2, varscan2
- GBP2 | c.429-26G>A | Intron (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
- GDA | c.*999T>C | 3'UTR (SNP) | VAF 32/73 reads (44%) | called by muse, mutect2, varscan2
- GLI3 | c.*1469C>T | 3'UTR (SNP) | VAF 25/90 reads (28%) | called by muse, mutect2, varscan2
- GNG7 | c.-78+3328C>A | Intron (SNP) | VAF 185/284 reads (65%) | catalogued as COSV66284558; called by muse, mutect2, varscan2
- HARS1 | c.1194+122G>A | Intron (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- HPS1 | c.398+62G>A | Intron (SNP) | VAF 14/26 reads (54%) | catalogued as rs550612426; called by muse, mutect2
- INTS13 | c.*51G>T | 3'UTR (SNP) | VAF 81/193 reads (42%) | called by muse, mutect2, varscan2
- KIF26A | chr14:104180608 G>A | 3'Flank (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- LIG3 | c.*4627T>C | 3'UTR (SNP) | VAF 45/101 reads (45%) | called by muse, mutect2, varscan2
- LPGAT1 | c.*5807C>T | 3'UTR (SNP) | VAF 12/80 reads (15%) | catalogued as rs185842209; called by muse, mutect2, varscan2
- LRATD1 | c.*3918C>G | 3'UTR (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- MECP2 | c.*6575G>A | 3'UTR (SNP) | VAF 71/176 reads (40%) | catalogued as rs1275523085; called by muse, mutect2, varscan2
- MGAM | c.4619-8767C>A | Intron (SNP) | VAF 34/144 reads (24%) | catalogued as rs776287872; called by muse, mutect2, varscan2
- MIP | c.*1230T>G | 3'UTR (SNP) | VAF 10/19 reads (53%) | catalogued as rs1440665212; called by muse, mutect2, varscan2
- MUC2 | chr11:1099528 C>T | 5'Flank (SNP) | VAF 25/107 reads (23%) | catalogued as rs530828858; called by muse, mutect2, varscan2
- MYRFL | c.-165C>G | 5'UTR (SNP) | VAF 29/72 reads (40%) | called by muse, mutect2, varscan2
- NCOR1 | c.6679+1981A>T | Intron (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- NR3C2 | c.*1045C>A | 3'UTR (SNP) | VAF 21/54 reads (39%) | catalogued as rs1197898535; called by muse, mutect2, varscan2
- OR10AG1 | c.*4G>T | 3'UTR (SNP) | VAF 72/191 reads (38%) | catalogued as rs1044942608; called by muse, mutect2, varscan2
- PAPOLB | c.*211G>A | 3'UTR (SNP) | VAF 38/119 reads (32%) | catalogued as rs925964155; called by muse, mutect2, varscan2
- PBX2P1 | n.129dup | RNA (INS) | VAF 20/50 reads (40%) | catalogued as rs1200067574; called by mutect2, pindel
- PCDH15 | c.2868+927A>T | Intron (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- PCDHA13 | c.*246C>T | 3'UTR (SNP) | VAF 84/496 reads (17%) | called by muse, mutect2, varscan2
- PCSK6 | c.2813-52G>T | Intron (SNP) | VAF 48/140 reads (34%) | called by muse, mutect2, varscan2
- PI15 | c.*4778T>G | 3'UTR (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2
- PLD1 | c.*1758T>A | 3'UTR (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- PNO1 | c.-26C>T | 5'UTR (SNP) | VAF 85/193 reads (44%) | called by muse, mutect2, varscan2
- PYGO1 | c.*6082C>G | 3'UTR (SNP) | VAF 34/111 reads (31%) | called by muse, mutect2, varscan2
- RARB | c.179-32872A>C | Intron (SNP) | VAF 42/95 reads (44%) | called by muse, mutect2, varscan2
- RIMS4 | c.*1014A>T | 3'UTR (SNP) | VAF 43/196 reads (22%) | catalogued as rs529706430, COSV65719433; called by muse, mutect2, varscan2
- RNF125 | c.*3969A>T | 3'UTR (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- RUNX1 | c.724+13043C>T | Intron (SNP) | VAF 29/113 reads (26%) | called by muse, mutect2, varscan2
- SEC63 | c.*2815T>G | 3'UTR (SNP) | VAF 36/62 reads (58%) | called by muse, mutect2, varscan2
- SEC63 | c.*2012T>A | 3'UTR (SNP) | VAF 31/54 reads (57%) | called by muse, mutect2, varscan2
- SF1 | c.*1054C>T | 3'UTR (SNP) | VAF 19/48 reads (40%) | catalogued as rs1220723830; called by muse, mutect2, varscan2
- SLC1A6 | chr19:14972921 C>T | 5'Flank (SNP) | VAF 6/22 reads (27%) | catalogued as rs1319458140; called by muse, mutect2
- SLC44A5 | c.*143C>T | 3'UTR (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- SLITRK1 | c.*2181T>G | 3'UTR (SNP) | VAF 10/11 reads (91%) | called by muse, mutect2, varscan2
- TDRD1 | c.*38T>A | 3'UTR (SNP) | VAF 221/469 reads (47%) | called by muse, mutect2, varscan2
- TEKT4 | c.499-617G>T | Intron (SNP) | VAF 17/123 reads (14%) | called by muse, mutect2, varscan2
- TGM2 | c.*685G>A | 3'UTR (SNP) | VAF 54/152 reads (36%) | called by muse, mutect2, varscan2
- TIFA | c.*769T>A | 3'UTR (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- TSR2 | c.*1889G>A | 3'UTR (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- VCL | c.783+2766C>T | Intron (SNP) | VAF 103/229 reads (45%) | called by muse, mutect2, varscan2
- WAPL | c.*300C>G | 3'UTR (SNP) | VAF 24/67 reads (36%) | called by muse, mutect2, varscan2
